Somatic mutation profile of tumor specimen TCGA-86-8056-01A (aliquot TCGA-86-8056-01A-11D-2238-08) from TCGA case TCGA-86-8056, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 64.0 years (23,369 days).
Specimen TCGA-86-8056-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95ed9546-4bd8-4b48-b664-1e38829b23e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8056-10A (Blood Derived Normal), aliquot TCGA-86-8056-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afe8896f-ed8a-4c9a-972a-2b2b85afd56c

The open-access MAF lists 295 somatic variants for this specimen: 234 protein-altering or splice-affecting, 59 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 208, Silent 59, Nonsense Mutation 13, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 3, Splice Region 2, Intron 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/46 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3662G>A p.R1221K | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99793041; called by muse, mutect2, varscan2
- ABHD17C | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99358691; called by muse, mutect2
- ADAMTS2 | c.3120C>A p.Y1040* | Nonsense Mutation (SNP) | VAF 343/669 reads (51%) | catalogued as COSV52387098, COSV99283822; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV100389253; called by muse, mutect2
- ADGRB3 | c.2897C>T p.S966L | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53236910; called by muse, mutect2, varscan2
- AKAP9 | c.3737G>A p.R1246K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV100663077; called by muse, mutect2
- AKR1C4 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as COSV99578906; called by muse, mutect2, varscan2
- AL592490.1 | c.2695G>T p.G899C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV101308283; called by muse, mutect2, varscan2
- ANKS6 | c.2096C>G p.S699C | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as COSV100782387; called by muse, mutect2
- APOA1 | c.391_393del p.K131del | In Frame Del (DEL) | VAF 18/104 reads (17%) | catalogued as rs532489785; called by pindel, varscan2
- ARHGAP21 | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100903708, COSV64545401; called by muse, mutect2, varscan2
- ATG9A | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs761352054, COSV100772668; called by muse, mutect2, varscan2
- ATP4A | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 72/345 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs1238988064, COSV99383078; called by muse, mutect2, varscan2
- ATXN2L | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs776614927, COSV57366960; called by muse, mutect2, varscan2
- BHMT2 | c.1029G>T p.W343C | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99670293; called by muse, mutect2, varscan2
- C7orf25 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as COSV100623669; called by muse, mutect2
- CCDC178 | c.348+1G>T p.X116_splice | Splice Site (SNP) | VAF 30/132 reads (23%) | catalogued as COSV100286699, COSV55760862; called by muse, mutect2, varscan2
- CCDC77 | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99520066; called by muse, mutect2, varscan2
- CCNB3 | c.1058A>G p.Q353R | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV99329845; called by muse, mutect2, varscan2
- CEACAM4 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as rs200115429, COSV55731905, COSV99701214; called by muse, mutect2, varscan2
- CFAP100 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100729430; called by muse, mutect2, varscan2
- CFAP251 | c.1899G>T p.W633C | Missense Mutation (SNP) | VAF 42/358 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996477; called by muse, mutect2, varscan2
- CFAP299 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as COSV100812504; called by muse, mutect2, varscan2
- CIC | c.4235G>T p.R1412L | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV50700657, COSV99360267; called by muse, mutect2, varscan2
- CNBD1 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV101575303; called by muse, mutect2
- CNGB3 | c.1145C>A p.T382N | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV60695074; called by muse, mutect2, varscan2
- CNTN5 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV54341364; called by muse, mutect2, varscan2
- CNTNAP4 | c.2957G>A p.C986Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100273311, COSV56678647; called by muse, mutect2, varscan2
- COA4 | c.195G>C p.M65I | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV100142720; called by muse, mutect2, varscan2
- COA4 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV100142723; called by muse, mutect2, varscan2
- COL6A3 | c.2534C>T p.S845L | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99801362; called by muse, mutect2, varscan2
- COLQ | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101082518; called by muse, mutect2
- CPLX3 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV100547840, COSV59002976; called by muse, mutect2, varscan2
- CPNE2 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99321613; called by muse, varscan2
- CSF1R | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV99643018; called by muse, mutect2, varscan2
- CTU2 | c.457T>A p.F153I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as rs768820327, COSV99966554; called by muse, mutect2, varscan2
- CYP7B1 | c.1382A>T p.Q461L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as COSV100042927; called by muse, mutect2, varscan2
- DCLRE1A | c.2533G>T p.E845* | Nonsense Mutation (SNP) | VAF 50/245 reads (20%) | catalogued as COSV100800485; called by muse, mutect2, varscan2
- DCLRE1A | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV100800488; called by muse, mutect2, varscan2
- DCST2 | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.959); catalogued as rs1313022208, COSV99421541; called by muse, mutect2, varscan2
- DNASE2 | c.264C>A p.S88R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV99322501; called by muse, mutect2, varscan2
- DTX2 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 84/985 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100184840; called by muse, mutect2
- DYSF | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99248926, COSV99250348; called by muse, varscan2
- EHD2 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs747209337, COSV99622234; called by muse, mutect2, varscan2
- EHHADH | c.468A>C p.R156S | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV99213362; called by muse, mutect2, varscan2
- ENC1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs61758147, COSV56629644; called by muse, mutect2, varscan2
- ENOX1 | c.1611+1G>A p.X537_splice | Splice Site (SNP) | VAF 46/330 reads (14%) | catalogued as COSV99817126; called by muse, mutect2, varscan2
- EPHA7 | c.2655G>C p.Q885H | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV100994342; called by muse, mutect2, varscan2
- FAM47B | c.634C>A p.R212S | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.037); catalogued as COSV100264635, COSV61457176; called by muse, mutect2, varscan2
- FAM83F | c.685G>T p.V229F | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs775091896, COSV100329089; called by muse, mutect2, varscan2
- FAR2 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456494412, COSV99478754; called by muse, mutect2, varscan2
- FAT4 | c.10079C>A p.S3360Y | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100630122; called by muse, mutect2
- FBXO10 | c.627G>C p.E209D | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1489931658, COSV99447247; called by muse, mutect2, varscan2
- FGF22 | c.258C>G p.I86M | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs1387909111, COSV99293823; called by muse, mutect2, varscan2
- FHIT | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100535454; called by muse, mutect2
- FLG | c.10294G>C p.D3432H | Missense Mutation (SNP) | VAF 144/1286 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100912179; called by muse, mutect2, varscan2
- FLG | c.6007G>C p.E2003Q | Missense Mutation (SNP) | VAF 139/2050 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as rs751507111, COSV100912180, COSV64237411; called by muse, mutect2
- FLG2 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV101166213; called by muse, mutect2, varscan2
- FOXK2 | c.1760C>G p.T587S | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs919771574, COSV100082439; called by muse, mutect2, varscan2
- FRMPD4 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV101044054; called by muse, mutect2, varscan2
- FSIP2 | c.18874G>C p.A6292P | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100556472; called by muse, mutect2
- FYCO1 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 27/309 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99946239; called by muse, mutect2
- GABRA4 | c.1078C>G p.Q360E | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV51935107, COSV99974688; called by muse, mutect2, varscan2
- GLE1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV100012792; called by muse, mutect2
- GPALPP1 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775026805, COSV100689267; called by muse, mutect2, varscan2
- GTF3C1 | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV100649695, COSV62238787; called by muse, mutect2, varscan2
- GUK1 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs964071558, COSV100451688, COSV100451806; called by muse, mutect2, varscan2
- HCFC1R1 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV99560808; called by muse, mutect2, varscan2
- HCN4 | c.2309C>A p.T770K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); catalogued as COSV99984214; called by muse, mutect2, varscan2
- HEATR3 | c.1786T>C p.S596P | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV99590115; called by muse, mutect2, varscan2
- HELB | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV99922211; called by muse, mutect2, varscan2
- HEPH | c.552C>G p.I184M (on ENST00000343002; = p.I238M on NM_138737.5) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.739); catalogued as COSV100295699; called by muse, mutect2
- HIVEP3 | c.1791G>C p.L597F | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV56011145, COSV99913970; called by muse, mutect2, varscan2
- HLX | c.758A>G p.Q253R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV100854620; called by muse, varscan2
- HNRNPF | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100563289; called by muse, mutect2, varscan2
- HPSE2 | c.513T>G p.D171E | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV100986271; called by muse, mutect2, varscan2
- HSPA8 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99914588, COSV99914622; called by muse, mutect2, varscan2
- HTATSF1 | c.272A>T p.D91V | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV99511900; called by muse, mutect2, varscan2
- IFI16 | c.1774G>C p.E592Q (on ENST00000295809 / NM_001364867.2; = p.E536Q on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV99858166; called by muse, mutect2
- INSR | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs758427733, COSV100253453, COSV57171896; called by muse, mutect2, varscan2
- ITGA10 | c.2404C>T p.Q802* | Nonsense Mutation (SNP) | VAF 23/165 reads (14%) | catalogued as COSV100995045; called by muse, mutect2, varscan2
- KAT6A | c.4543G>A p.E1515K | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99705869; called by muse, mutect2, varscan2
- KAT8 | c.601T>A p.Y201N | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99571789; called by muse, mutect2, varscan2
- KBTBD6 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as rs1487340078, COSV101068860; called by muse, mutect2
- KCNH8 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100111023; called by muse, mutect2, varscan2
- KCNIP2 | c.271G>A p.E91K (on ENST00000356640 / NM_173191.3; = p.E106K on NM_014591.5) | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs945367630, COSV99493618; called by muse, mutect2, varscan2
- KCNJ6 | c.53A>T p.D18V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.058); catalogued as rs1167413917, COSV99900518; called by muse, mutect2, varscan2
- KIF21B | c.3913G>A p.E1305K (on ENST00000422435 / NM_001252100.2; = p.E1292K on NM_017596.4) | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760306875, COSV59761008; called by muse, mutect2, varscan2
- KLHDC3 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV99763920; called by muse, mutect2, varscan2
- KLK6 | c.525G>C p.Q175H | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV100037848; called by muse, mutect2, varscan2
- KMT2C | c.5608C>T p.Q1870* | Nonsense Mutation (SNP) | VAF 18/135 reads (13%) | catalogued as COSV51506876; called by muse, mutect2, varscan2
- KRBA1 | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs1451829279, COSV99753110; called by muse, mutect2, varscan2
- LACC1 | c.632A>G p.N211S | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765524994, COSV100354793; called by muse, mutect2, varscan2
- LARP4B | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs775441779, COSV100295663; called by muse, mutect2, varscan2
- LCK | c.1264G>C p.D422H | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100288143; called by muse, mutect2
- LEF1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs1374631633, COSV54471070, COSV99490028; called by muse, mutect2, varscan2
- LEKR1 | c.*1144G>A | Splice Region (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100739301; called by muse, mutect2
- LEPR | c.2824C>G p.L942V | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); catalogued as COSV100848420; called by muse, mutect2, varscan2
- LINS1 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100130536, COSV59080061; called by muse, mutect2, varscan2
- LMOD2 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as rs1047347138, COSV101505467; called by muse, mutect2, varscan2
- LONP1 | c.716C>G p.S239* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100638753, COSV62261345; called by muse, mutect2, varscan2
- LRIF1 | c.1262C>G p.S421C | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs774996546, COSV100870924, COSV63897250; called by muse, mutect2, varscan2
- LRIF1 | c.474A>T p.K158N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100870925; called by muse, mutect2, varscan2
- LRRC15 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.038); catalogued as COSV100752925; called by muse, mutect2, varscan2
- LRRC7 | c.712-1G>T p.X238_splice (on ENST00000651989 / NM_001370785.2; = p.X205_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 62/229 reads (27%) | catalogued as COSV50420325, COSV99226266; called by muse, mutect2, varscan2
- LRRTM4 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | catalogued as COSV69139539; called by muse, mutect2, varscan2
- LY6K | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs144411665; called by muse, mutect2, varscan2
- MAGEC3 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV53577989; called by muse, mutect2, varscan2
- MANBA | c.1885C>T p.L629F (on ENST00000642252; = p.L583F on NM_005908.4) | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.029); catalogued as rs115145808, COSV99899190; called by muse, mutect2, varscan2
- MAP1B | c.3059C>A p.A1020D | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99702931; called by muse, mutect2, varscan2
- MED12L | c.5723C>T p.P1908L | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.236); catalogued as rs779962238, COSV56395200; called by muse, mutect2, varscan2
- MFSD1 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs774689203; called by muse, mutect2
- MIB1 | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs1483489029, COSV99839457; called by muse, mutect2, varscan2
- MIGA2 | c.1403C>A p.T468K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99477879; called by muse, mutect2, varscan2
- MS4A14 | c.1239T>A p.H413Q | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100280728; called by muse, mutect2, varscan2
- MUC6 | c.3785C>T p.S1262F | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV101424788; called by muse, mutect2, varscan2
- MYBPC2 | c.2767G>A p.A923T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1387947267, COSV63093953; called by muse, mutect2
- MYCN | c.13T>A p.S5T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs868623724, COSV99808542; called by muse, mutect2, varscan2
- MYNN | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100582340, COSV62992355; called by muse, mutect2, varscan2
- MYO18A | c.3973G>C p.E1325Q | Missense Mutation (SNP) | VAF 46/429 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV100572713; called by muse, mutect2, varscan2
- MYRIP | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs767587141, COSV100219990; called by muse, mutect2, varscan2
- NAALAD2 | c.732G>C p.Q244H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100428808, COSV58961840; called by muse, mutect2
- NAV2 | c.1321G>A p.E441K (on ENST00000396087 / NM_001244963.2; = p.E418K on NM_145117.5) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.142); catalogued as COSV100586982; called by muse, mutect2, varscan2
- NAV2 | c.6532G>T p.E2178* (on ENST00000396087 / NM_001244963.2; = p.E2119* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 44/175 reads (25%) | catalogued as COSV100217631; called by muse, mutect2, varscan2
- NAV3 | c.6826G>C p.G2276R (on ENST00000397909 / NM_001024383.2; = p.G2254R on NM_014903.6) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99895501, COSV99897468; called by muse, mutect2, varscan2
- NCAPD2 | c.2539G>C p.E847Q | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.265); catalogued as COSV100217440; called by muse, mutect2, varscan2
- NCOA3 | c.1005C>G p.F335L | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100508198, COSV59074533; called by muse, mutect2, varscan2
- NLRP2 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99672644; called by muse, mutect2
- NOL4 | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV52336534, COSV99308319; called by muse, mutect2, varscan2
- NOTCH3 | c.5053G>A p.D1685N | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.334); catalogued as COSV54632372; called by muse, mutect2, varscan2
- NRXN2 | c.2876C>A p.S959* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV55450576, COSV99635738; called by muse, mutect2, varscan2
- NUP50 | c.664C>G p.P222A | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs755413949, COSV100754416; called by muse, mutect2, varscan2
- OBSCN | c.21899C>T p.S7300F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV100805512; called by muse, mutect2, varscan2
- OPN1LW | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as COSV100886952; called by muse, mutect2, varscan2
- OR10S1 | c.379T>A p.F127I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV101602505; called by muse, mutect2, varscan2
- OR5B2 | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.125); catalogued as COSV100222969; called by muse, mutect2, varscan2
- OR8H1 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100477348; called by muse, mutect2, varscan2
- OSBPL3 | c.1044G>T p.R348S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV100514528; called by muse, mutect2, varscan2
- OVCH1 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.187); catalogued as COSV100549196; called by muse, mutect2, varscan2
- PALD1 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs143276983; called by muse, mutect2, varscan2
- PAPPA2 | c.1856A>G p.Y619C | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV100867144; called by muse, mutect2, varscan2
- PARP4 | c.613A>C p.K205Q | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.087); catalogued as COSV101132045; called by muse, mutect2, varscan2
- PCDH11X | c.2671A>T p.T891S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100015196; called by muse, varscan2
- PCDHA5 | c.1667A>G p.D556G | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100972529; called by muse, mutect2, varscan2
- PCDHB11 | c.1883G>T p.R628M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100697173; called by mutect2, varscan2
- PDE3A | c.435G>T p.W145C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV100762785; called by muse, varscan2
- PDS5B | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV100221505; called by muse, mutect2
- PEG3 | c.4402C>A p.P1468T | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV99690348; called by muse, mutect2, varscan2
- PLIN2 | c.167C>G p.T56S | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.338); catalogued as COSV99439191; called by muse, mutect2, varscan2
- PLXNB3 | c.5314G>A p.D1772N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737916; called by muse, mutect2, varscan2
- POFUT2 | c.868G>C p.G290R | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV100499412; called by muse, mutect2, varscan2
- POSTN | c.1170A>T p.Q390H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101123494; called by muse, mutect2, varscan2
- POTEE | c.970C>G p.L324V | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV100387822, COSV100389307; called by muse, mutect2, varscan2
- PRDM8 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); catalogued as COSV100325349; called by muse, mutect2, varscan2
- PREX1 | c.3450G>T p.K1150N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.047); catalogued as COSV100906803; called by muse, mutect2, varscan2
- PTCHD1 | c.2614G>C p.E872Q | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV101037998, COSV65063144; called by muse, mutect2, varscan2
- PTDSS2 | c.862A>T p.M288L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100339303; called by muse, mutect2, varscan2
- PTPRS | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV99510222, COSV99512362; called by muse, mutect2, varscan2
- PTPRT | c.2398C>A p.P800T | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.141); catalogued as COSV100630416; called by muse, mutect2, varscan2
- PTPRT | c.1400C>A p.P467H | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100630417; called by muse, mutect2, varscan2
- RAB11FIP2 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV100843132; called by muse, mutect2, varscan2
- RABGGTB | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV99592523; called by muse, mutect2, varscan2
- RASAL3 | c.1558T>A p.Y520N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100640336; called by muse, mutect2
- RASIP1 | c.2232G>C p.L744F | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV99711099; called by muse, mutect2
- RB1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57325375, COSV99926730; called by muse, mutect2
- RCAN1 | c.563A>T p.Y188F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.953); catalogued as COSV100571722; called by muse, mutect2, varscan2
- RHOG | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV99544592; called by muse, mutect2, varscan2
- RIMS2 | c.2962G>T p.V988F (on ENST00000666250 / NM_001348490.2; = p.V796F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.732); catalogued as COSV51671251; called by muse, mutect2, varscan2
- RNF165 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.076); catalogued as COSV99492075; called by muse, mutect2, varscan2
- ROR2 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 99/742 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100996108; called by muse, mutect2, varscan2
- RRAGA | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100998170; called by muse, mutect2, varscan2
- SAGE1 | c.1276C>A p.P426T | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV100187898; called by muse, mutect2, varscan2
- SEC14L3 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 10/253 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV99307311; called by muse, mutect2
- SERPINA12 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.374); catalogued as COSV100369817; called by muse, mutect2, varscan2
- SERPINB9 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs769420208, COSV66233381; called by muse, mutect2, varscan2
- SIGIRR | c.497A>T p.D166V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100230298; called by muse, varscan2
- SIN3B | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV99932045; called by muse, mutect2
- SKAP1 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV100412296; called by muse, mutect2, varscan2
- SLC3A2 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV58605331; called by muse, mutect2, varscan2
- SLC44A2 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs571972029, COSV100213457; called by muse, mutect2, varscan2
- SLC45A3 | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100901330; called by muse, mutect2, varscan2
- SLC45A3 | c.1384G>T p.G462W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100901069, COSV100901331; called by muse, mutect2, varscan2
- SLC4A7 | c.2538G>C p.K846N | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99840340; called by muse, mutect2, varscan2
- SMYD3 | c.784G>A p.D262N (on ENST00000490107 / NM_001375962.1; = p.D203N on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV100830952; called by muse, mutect2, varscan2
- SOX14 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100048341; called by muse, mutect2, varscan2
- SPEN | c.3760G>C p.D1254H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101005591, COSV65369606; called by muse, mutect2
- SPEN | c.4720G>A p.D1574N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs138972634; called by muse, mutect2, varscan2
- SPPL2C | c.1819G>T p.A607S | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV100234159; called by muse, mutect2
- ST3GAL6 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1175080452, COSV99505250; called by muse, mutect2
- TBC1D21 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs142388512, COSV100311560; called by muse, mutect2, varscan2
- TEK | c.3196G>A p.E1066K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs762495403, COSV101193556; called by muse, mutect2, varscan2
- TENM3 | c.6028G>A p.D2010N | Missense Mutation (SNP) | VAF 38/448 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.587); catalogued as COSV101305461; called by muse, mutect2
- THBS2 | c.1122C>A p.C374* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV64682298; called by muse, mutect2, varscan2
- TMCC2 | c.1318G>C p.D440H | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100319534; called by muse, varscan2
- TMEM117 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99861886; called by muse, mutect2, varscan2
- TMEM245 | c.1854G>T p.S618= | Splice Region (SNP) | VAF 10/50 reads (20%) | catalogued as COSV101002469; called by muse, mutect2, varscan2
- TMX4 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99851644; called by muse, mutect2, varscan2
- TNC | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs901142297, COSV100406246; called by muse, mutect2, varscan2
- TNRC6A | c.5686G>A p.D1896N | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs765754892, COSV59368286; called by muse, mutect2
- TP53 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs587781845, COSV52671445, COSV52701260, COSV52703282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53INP1 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); catalogued as COSV100711138; called by muse, mutect2
- TPH2 | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV100422366; called by muse, mutect2, varscan2
- TRPM4 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs750673849, COSV53267641; called by muse, mutect2, varscan2
- TSPYL2 | c.2051C>A p.A684D | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100966365; called by muse, mutect2
- TTBK2 | c.3104C>T p.S1035L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99142459; called by muse, mutect2, varscan2
- USP4 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as COSV55539136, COSV99649742; called by muse, mutect2, varscan2
- USP48 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as COSV57614985; called by muse, mutect2, varscan2
- VTA1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.029); catalogued as COSV100859264; called by muse, varscan2
- VWC2L | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100436325, COSV56975343; called by muse, mutect2, varscan2
- WDR1 | c.1140C>G p.I380M (on ENST00000382452; = p.I240M on NM_005112.5) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as COSV101221155, COSV66724039; called by muse, mutect2, varscan2
- WRN | c.871A>T p.N291Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99989884; called by muse, mutect2, varscan2
- WWC1 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV99515892; called by muse, mutect2, varscan2
- XIRP2 | c.655G>A p.E219K (on ENST00000628543; = p.E394K on NM_152381.6) | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs761386745, COSV99738093, COSV99747300; called by muse, mutect2, varscan2
- XIRP2 | c.6574C>T p.P2192S (on ENST00000628543; = p.P2367S on NM_152381.6) | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.782); catalogued as rs376097885; called by muse, mutect2, varscan2
- YIPF2 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as rs1290470333; called by muse, mutect2
- ZBTB7C | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100134599; called by muse, mutect2
- ZC3H12C | c.1639C>G p.H547D | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.622); catalogued as COSV99585320; called by muse, mutect2, varscan2
- ZNF280C | c.794C>A p.T265N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100921270; called by muse, mutect2, varscan2
- ZNF521 | c.1972G>C p.D658H | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100833387; called by muse, mutect2
- ZNF536 | c.1908C>A p.C636* | Nonsense Mutation (SNP) | VAF 71/307 reads (23%) | catalogued as COSV100835870, COSV62822641; called by muse, mutect2, varscan2
- ZNF567 | c.1738C>G p.Q580E (on ENST00000536254 / NM_001322913.1; = p.Q549E on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV100658984; called by muse, mutect2, varscan2
- ZNF574 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV99726486; called by muse, mutect2, varscan2
- ZNF641 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs563221165, COSV99973671; called by muse, mutect2, varscan2
- ZNF8 | c.1439C>G p.S480C | Missense Mutation (SNP) | VAF 56/417 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761987109, COSV99544548; called by muse, mutect2, varscan2
- ZNF836 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.075); catalogued as rs760954576, COSV100441263; called by muse, mutect2, varscan2
- CHRNB3 | c.1031del p.P344Qfs*6 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | called by mutect2, pindel, varscan2
- IL7R | c.831del p.D278Ifs*17 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- LCA5L | c.1626dup p.P543Afs*12 | Frame Shift Ins (INS) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- MLPH | c.769dup p.H257Pfs*19 | Frame Shift Ins (INS) | VAF 19/86 reads (22%) | called by mutect2, pindel, varscan2
- NRXN1 | c.3526del p.D1176Tfs*3 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- OR52E8 | c.618dup p.G207Wfs*66 | Frame Shift Ins (INS) | VAF 28/117 reads (24%) | called by mutect2, pindel, varscan2
- POTEA | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.92); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- UBE3D | c.741_750del p.W248Rfs*3 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel
- ALDH3B2 | c.16C>A p.R6= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV100824125; called by muse, mutect2, varscan2
- ATRIP | c.6G>A p.A2= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs1471932302, COSV100202954; called by muse, mutect2, varscan2
- AWAT1 | c.798G>T p.G266= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV100997233; called by muse, mutect2, varscan2
- BCORL1 | c.4725C>A p.L1575= | Silent (SNP) | VAF 56/293 reads (19%) | catalogued as COSV99500886; called by muse, mutect2, varscan2
- CCDC93 | c.906T>C p.A302= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100099466; called by muse, varscan2
- CDT1 | c.60C>T p.I20= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1250753922, COSV56347303, COSV56348860; called by muse, varscan2
- CHL1 | c.1080C>T p.P360= (on ENST00000397491 / NM_001253387.1; = p.P376= on NM_006614.4) | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs968055510, COSV99852297; called by muse, mutect2, varscan2
- CNKSR2 | c.348C>G p.T116= | Silent (SNP) | VAF 30/203 reads (15%) | catalogued as COSV54257295, COSV99669702; called by muse, mutect2, varscan2
- DSCAML1 | c.6192G>T p.P2064= (on ENST00000321322; = p.P2004= on NM_020693.4) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100357217; called by muse, mutect2, varscan2
- DYSF | c.177G>C p.L59= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV99250346; called by muse, mutect2, varscan2
- ERCC6 | c.2602C>T p.L868= | Silent (SNP) | VAF 49/182 reads (27%) | catalogued as COSV100876196; called by muse, mutect2, varscan2
- ERCC6L | c.3752G>A p.*1251= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs1343048635, COSV100558945, COSV100559252; called by muse, mutect2
- EVC | c.1893G>T p.T631= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as COSV99382532; called by muse, mutect2, varscan2
- FAM76A | c.603C>T p.F201= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as rs1163814047, COSV99159666; called by muse, mutect2, varscan2
- FAM83G | c.936C>G p.L312= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV100525505, COSV58755028; called by muse, mutect2, varscan2
- GRM6 | c.543C>T p.L181= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV99179931; called by muse, mutect2, varscan2
- HEPH | c.2124G>T p.G708= (on ENST00000343002; = p.G441= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV100295704, COSV57960828; called by muse, mutect2, varscan2
- HEXB | c.1011C>T p.F337= | Silent (SNP) | VAF 24/234 reads (10%) | catalogued as COSV99784465; called by muse, mutect2
- HIVEP1 | c.7278C>T p.L2426= | Silent (SNP) | VAF 25/189 reads (13%) | catalogued as COSV101045722; called by muse, mutect2, varscan2
- HNRNPL | c.99G>A p.V33= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99670564; called by muse, mutect2
- KIF1A | c.2265G>C p.T755= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100242288; called by muse, mutect2, varscan2
- KNCN | c.273C>A p.S91= (on ENST00000481882 / NM_001322255.2; = p.S68= on NM_001097611.1) | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99606354; called by muse, mutect2, varscan2
- LRP1 | c.7035C>T p.L2345= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV99677180; called by muse, mutect2, varscan2
- MAGED1 | c.882G>A p.V294= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100431815; called by muse, mutect2, varscan2
- MAP7D3 | c.2373A>G p.L791= | Silent (SNP) | VAF 158/487 reads (32%) | catalogued as COSV100286361, COSV60170172; called by muse, mutect2, varscan2
- MGAM | c.3792T>C p.D1264= | Silent (SNP) | VAF 93/336 reads (28%) | catalogued as COSV72074776; called by muse, mutect2, varscan2
- MPI | c.1110C>T p.L370= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs1167720956, COSV100086385; called by muse, mutect2, varscan2
- MUC16 | c.4479C>A p.S1493= | Silent (SNP) | VAF 84/268 reads (31%) | catalogued as COSV101201588; called by muse, mutect2, varscan2
- MYO7A | c.1653C>T p.I551= | Silent (SNP) | VAF 74/299 reads (25%) | catalogued as COSV101289265; called by muse, mutect2, varscan2
- NDUFAF5 | c.9G>A p.R3= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs201860210, COSV99176504; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOTCH3 | c.1308G>T p.L436= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs767459278, COSV99658776; called by muse, mutect2, varscan2
- NPAS2 | c.1626C>G p.V542= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV100176944; called by muse, mutect2, varscan2
- NRCAM | c.2472G>T p.L824= (on ENST00000379028 / NM_001371124.1; = p.L808= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV100695463, COSV61047921; called by muse, mutect2, varscan2
- NRK | c.4404G>A p.L1468= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV54606342, COSV99689140; called by muse, mutect2, varscan2
- OR10G8 | c.624C>A p.G208= | Silent (SNP) | VAF 26/174 reads (15%) | catalogued as rs949919640, COSV101461879; called by muse, mutect2, varscan2
- OR4Q3 | c.420C>A p.R140= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as COSV100057371; called by muse, mutect2, varscan2
- OR8G1 | c.504C>T p.F168= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100422664; called by muse, mutect2, varscan2
- PAGE2 | c.271A>C p.R91= | Silent (SNP) | VAF 37/259 reads (14%) | catalogued as COSV100892317; called by muse, mutect2, varscan2
- PCNX2 | c.2013C>A p.I671= | Silent (SNP) | VAF 37/137 reads (27%) | catalogued as COSV99269448; called by muse, mutect2, varscan2
- PIKFYVE | c.3303G>A p.R1101= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV100011436; called by muse, mutect2, varscan2
- PLOD3 | c.753G>T p.V251= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV99778286; called by muse, mutect2, varscan2
- PLPP1 | c.423C>A p.I141= | Silent (SNP) | VAF 38/236 reads (16%) | catalogued as rs566357496, COSV53304968, COSV99302029; called by muse, mutect2, varscan2
- POLR3A | c.2002C>T p.L668= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV100965798; called by muse, varscan2
- PYGM | c.693G>A p.V231= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs1327930001, COSV99377601; called by muse, mutect2, varscan2
- RAB3GAP1 | c.876C>T p.I292= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV99921765; called by muse, mutect2, varscan2
- RASGRF2 | c.378G>A p.E126= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99430320; called by muse, mutect2, varscan2
- RNF34 | c.57C>T p.V19= | Silent (SNP) | VAF 21/188 reads (11%) | catalogued as COSV100772156; called by muse, mutect2, varscan2
- RYR2 | c.5361C>G p.L1787= | Silent (SNP) | VAF 19/207 reads (9%) | catalogued as COSV100772851; called by muse, mutect2
- SLC38A5 | c.1173C>A p.V391= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100476771; called by muse, mutect2, varscan2
- SLCO4C1 | c.264C>T p.Y88= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV60515298, COSV60520287; called by muse, mutect2
- SRC | c.528C>T p.L176= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as rs140204627; called by muse, mutect2, varscan2
- STMN4 | c.288G>A p.K96= (on ENST00000265770 / NM_001283054.2; = p.K123= on NM_030795.4) | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV56109590, COSV99741155; called by muse, mutect2, varscan2
- TAF7 | c.942C>G p.L314= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100515066; called by mutect2, varscan2
- TMCC2 | c.1383G>A p.L461= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs554528515, COSV100319537; called by muse, varscan2
- TUT4 | c.4119A>G p.P1373= | Silent (SNP) | VAF 140/556 reads (25%) | catalogued as COSV99932819; called by muse, mutect2, varscan2
- TXNDC16 | c.703T>C p.L235= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs1180467118, COSV99909648; called by muse, mutect2, varscan2
- USP34 | c.5082T>G p.S1694= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV101277206; called by muse, mutect2, varscan2
- ZDBF2 | c.5814G>A p.Q1938= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV100985530; called by muse, mutect2
- ZNF804A | c.3108C>T p.I1036= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs142448316, COSV56444107; called by muse, mutect2, varscan2
- NBPF11 | c.-549+2421G>A | Intron (SNP) | VAF 11/89 reads (12%) | catalogued as rs1267798121; called by muse, mutect2, varscan2
- TPM4 | chr19:16076098 G>T | 5'Flank (SNP) | VAF 4/11 reads (36%) | catalogued as rs1568299340, COSV99959549; called by muse, mutect2, varscan2
